Somatic mutation profile of tumor specimen BA2659D (aliquot aq-BA2659D) from BEATAML1.0 case 2057, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 86.1 years (31,465 days).
Specimen BA2659D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98e69897-31c9-42d5-96b4-788fdcae03a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2091D (Solid Tissue Normal), aliquot aq-BA2091D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6ec474e-4440-4aa7-8c0a-8c12a03c9655

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OVGP1 | c.1606A>G p.S536G | Missense Mutation (SNP) | VAF 4/12 reads (33%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs3767609, COSV63857328; ClinVar: benign; called by muse, varscan2
- KCNC1 | c.508C>A p.R170S | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV56392200; called by muse, mutect2
- FAM120A | c.682C>A p.L228M | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.241); called by muse, mutect2
- LYPD3 | c.91del p.L31Wfs*19 | Frame Shift Del (DEL) | VAF 46/108 reads (43%) | called by mutect2, varscan2
- SVIL | c.227G>T p.C76F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.031); called by muse, mutect2
- URB2 | c.1387C>A p.L463I | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF780B | c.752G>T p.C251F | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BTBD17 | c.531G>T p.V177= | Silent (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2
